Somatic mutation profile of tumor specimen C3N-00647-01 (aliquot CPT0210400010) from CPTAC case C3N-00647, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Tumor grade: G1.
Specimen C3N-00647-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e53143b7-3d77-4df3-8ddb-7f07fd24108d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00647-71 (Blood Derived Normal), aliquot CPT0210520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eb12e090-d706-432c-9190-68b590765ec6

The open-access MAF lists 74 somatic variants for this specimen: 48 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 17, Intron 5, Frame Shift Del 4, Splice Region 3, Nonsense Mutation 3, 3'Flank 2, Splice Site 2, Frame Shift Ins 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTSL4 | c.2102A>G p.D701G | Missense Mutation (SNP) | VAF 82/450 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs777396369; called by muse, mutect2, varscan2
- CCDC191 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.015); catalogued as rs1209120256; called by muse, mutect2, varscan2
- COPE | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 29/195 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.086); catalogued as rs771945064; called by muse, mutect2, varscan2
- CSMD3 | c.7319G>T p.G2440V (on ENST00000297405 / NM_001363185.1; = p.G2336V on NM_052900.3) | Missense Mutation (SNP) | VAF 77/276 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV52098328; called by muse, mutect2, varscan2
- DGKD | c.3298G>A p.D1100N (on ENST00000264057 / NM_152879.3; = p.D1056N on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs779504822; called by muse, mutect2, varscan2
- DSCAM | c.2893C>T p.R965W | Missense Mutation (SNP) | VAF 69/577 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV68029694; called by muse, mutect2, varscan2
- EBF4 | c.265G>C p.A89P (on ENST00000609451; = p.A85P on NM_001110514.1) | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100712408; called by muse, mutect2, varscan2
- MFSD2A | c.1273G>A p.D425N (on ENST00000372809 / NM_001136493.3; = p.D412N on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/262 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1038441258, COSV65685506; called by muse, mutect2, varscan2
- MYO1H | c.377G>A p.G126E | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375164407, COSV60446040; called by muse, mutect2, varscan2
- PHEX | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 69/478 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.232); catalogued as rs757539874, COSV65075837; called by muse, mutect2, varscan2
- PTPRZ1 | c.1984G>A p.A662T | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756500795, COSV66437561; called by muse, mutect2, varscan2
- SOX18 | c.388G>T p.E130* | Nonsense Mutation (SNP) | VAF 120/777 reads (15%) | catalogued as rs752364931; called by muse, mutect2, varscan2
- AKAP12 | c.34C>T p.P12S | Missense Mutation (SNP) | VAF 21/281 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.203); called by muse, mutect2
- ARL13B | c.826A>G p.K276E (on ENST00000394222 / NM_001174150.2; = p.K169E on NM_144996.4) | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BTD | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CAPN11 | c.939A>C p.E313D | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- CDK14 | c.269_273del p.V90Efs*5 (on ENST00000380050 / NM_001287135.2; = p.V72Efs*5 on NM_012395.3) | Frame Shift Del (DEL) | VAF 86/296 reads (29%) | called by mutect2, pindel, varscan2
- FER1L6 | c.3337G>T p.D1113Y | Missense Mutation (SNP) | VAF 52/198 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- GLS | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- JAML | c.426G>C p.E142D (on ENST00000356289 / NM_001098526.2; = p.E132D on NM_153206.3) | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- MGA | c.2963T>A p.L988* | Nonsense Mutation (SNP) | VAF 63/325 reads (19%) | called by muse, mutect2, varscan2
- MYH9 | c.1377dup p.D460* | Frame Shift Ins (INS) | VAF 132/540 reads (24%) | called by mutect2, pindel, varscan2
- NCAM1 | c.776A>G p.D259G | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2
- NECAP1 | c.677-1G>T p.X226_splice | Splice Site (SNP) | VAF 21/183 reads (11%) | called by muse, mutect2, varscan2
- NEUROD4 | c.577dup p.C193Lfs*2 | Frame Shift Ins (INS) | VAF 55/236 reads (23%) | called by mutect2, pindel, varscan2
- OR13H1 | c.817A>T p.I273F | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- PALLD | c.1768C>G p.P590A | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PBRM1 | c.2778del p.E927Kfs*87 (on ENST00000296302 / NM_001366071.2; = p.E927Kfs*81 on NM_018313.5) | Frame Shift Del (DEL) | VAF 7/50 reads (14%) | called by mutect2, pindel, varscan2
- PBX3 | c.1122+2T>C p.X374_splice | Splice Site (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- PHACTR2 | c.1573C>G p.P525A | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- POLQ | c.379T>G p.L127V | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- PPFIA2 | c.2391A>G p.R797= | Splice Region (SNP) | VAF 39/118 reads (33%) | called by muse, mutect2, varscan2
- PTK2 | c.2601A>C p.P867= | Splice Region (SNP) | VAF 36/138 reads (26%) | called by muse, mutect2, varscan2
- SDAD1 | c.124del p.V42Wfs*15 | Frame Shift Del (DEL) | VAF 20/86 reads (23%) | called by mutect2, pindel, varscan2
- SLC12A8 | c.1915C>A p.H639N | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- SMYD1 | c.754del p.Y252Ifs*15 | Frame Shift Del (DEL) | VAF 43/152 reads (28%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.6057G>A p.E2019= | Splice Region (SNP) | VAF 30/104 reads (29%) | called by muse, mutect2, varscan2
- STAT2 | c.109G>C p.V37L | Missense Mutation (SNP) | VAF 64/252 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- STK11IP | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TLR7 | c.2882A>G p.Y961C | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMC3 | c.2084T>G p.M695R | Missense Mutation (SNP) | VAF 31/230 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- TRIM51GP | c.54C>A p.C18* | Nonsense Mutation (SNP) | VAF 123/461 reads (27%) | called by muse, mutect2, varscan2
- TRIT1 | c.736G>T p.D246Y | Missense Mutation (SNP) | VAF 37/300 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- USF3 | c.2723A>T p.K908I | Missense Mutation (SNP) | VAF 82/307 reads (27%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- VWA3A | c.3376C>A p.L1126M | Missense Mutation (SNP) | VAF 51/450 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ZBP1 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF443 | c.1289T>G p.F430C | Missense Mutation (SNP) | VAF 52/302 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF750 | c.1684C>G p.Q562E | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.013); called by muse, mutect2
- ACAA2 | c.363C>T p.S121= | Silent (SNP) | VAF 13/190 reads (7%) | catalogued as rs774699358; called by muse, mutect2
- ACBD6 | c.42C>T p.D14= | Silent (SNP) | VAF 73/542 reads (13%) | catalogued as rs1216098353; called by muse, mutect2, varscan2
- ADGRG2 | c.2067G>A p.K689= (on ENST00000379869 / NM_001079858.3; = p.K686= on NM_005756.4) | Silent (SNP) | VAF 33/423 reads (8%) | catalogued as COSV61338320; called by muse, mutect2
- C10orf53 | c.454A>C p.R152= | Silent (SNP) | VAF 47/161 reads (29%) | called by muse, mutect2, varscan2
- CDCA5 | c.195G>A p.L65= | Silent (SNP) | VAF 29/262 reads (11%) | called by muse, varscan2
- GATB | c.1128C>T p.L376= | Silent (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2
- KIAA0895L | c.1296G>A p.L432= | Silent (SNP) | VAF 8/71 reads (11%) | called by muse, mutect2, varscan2
- MAP3K4 | c.1665A>G p.Q555= | Silent (SNP) | VAF 28/79 reads (35%) | called by muse, mutect2, varscan2
- MEP1B | c.2028T>C p.Y676= | Silent (SNP) | VAF 144/507 reads (28%) | called by muse, mutect2, varscan2
- SLC25A11 | c.702T>G p.T234= | Silent (SNP) | VAF 93/351 reads (26%) | called by muse, mutect2, varscan2
- SLC6A12 | c.807C>T p.Y269= | Silent (SNP) | VAF 39/274 reads (14%) | called by muse, mutect2, varscan2
- SYN2 | c.789G>A p.T263= | Silent (SNP) | VAF 21/269 reads (8%) | catalogued as rs750769489; called by muse, mutect2
- TRPS1 | c.915C>A p.T305= (on ENST00000220888 / NM_001330599.2; = p.T318= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- TTN | c.27690C>T p.N9230= (on ENST00000591111; = p.N8303= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/172 reads (29%) | catalogued as rs727505185; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBTB46 | c.96C>T p.D32= | Silent (SNP) | VAF 28/265 reads (11%) | catalogued as rs199552955, COSV55510221; called by muse, mutect2, varscan2
- ZNF318 | c.6039C>T p.A2013= | Silent (SNP) | VAF 50/201 reads (25%) | called by muse, mutect2, varscan2
- ZNF347 | c.1137G>A p.G379= | Silent (SNP) | VAF 7/130 reads (5%) | catalogued as COSV61967676; called by muse, mutect2
- GVINP1 | n.2680C>A | RNA (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
- MLX | c.*980C>T | 3'UTR (SNP) | VAF 9/115 reads (8%) | catalogued as rs1316446644; called by muse, mutect2
- RASGRP2 | c.-71-475G>C | Intron (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- SLC14A1 | c.-22+2285C>T | Intron (SNP) | VAF 22/334 reads (7%) | catalogued as rs1245066961; called by muse, mutect2
- SNORD116-17 | chr15:25088198 C>A | 3'Flank (SNP) | VAF 12/162 reads (7%) | called by muse, mutect2
- TEX35 | chr1:178525465 C>A | 3'Flank (SNP) | VAF 31/118 reads (26%) | called by muse, mutect2, varscan2
- TNRC6A | c.3694+15A>C | Intron (SNP) | VAF 5/26 reads (19%) | called by muse, mutect2
- UCKL1 | c.924-128C>T | Intron (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- ZNF841 | c.-78+7738C>A | Intron (SNP) | VAF 33/287 reads (11%) | catalogued as COSV101270699; called by muse, mutect2, varscan2
